Gene-level copy-number profile of tumor specimen ALCH-B1U8-TTP1-A from ALCHEMIST case ALCH-B1U8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.7 years (28,014 days).
Specimen ALCH-B1U8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed882f60-0fe5-4aca-bd30-73f5f22863d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1U8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/3d983774-e1fd-444a-885e-56ee16a7624f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 6,153; copy number 2: 31,253; copy number 3: 15,345; copy number 4: 2,638; copy number 5: 495; copy number 6: 1,243; copy number 7: 241; copy number 8: 177; copy number 9: 156; copy number 10: 359; copy number 11: 65; copy number 12: 2; copy number 13: 9; copy number 14: 81; copy number 15: 33; copy number 17: 8; copy number 18: 17.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–915,976, 3 genes: AL645608.6, AL645608.2, AL645608.4.
- chr3:73,382,431–84,893,379, 86 genes (broad region; genes not listed).
- chr3:85,385,710–85,385,792, 1 gene (within-gene range 0–3): MIR5688.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr13:66,630,715–66,630,776, 1 gene (within-gene range 0–1): RNU7-87P.
- chr16:64,943,753–65,938,453, 10 genes: CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1.
- chr17:9,547,298–9,555,696, 2 genes (within-gene range 0–1): AC087501.3, AC087501.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,807 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:975,204–982,093, 1 gene, copy number 5 (within-gene range 1–5): PERM1.
- chr1:157,830,911–158,579,899, 28 genes, copy number 5: CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1.
- chr1:159,346,166–161,371,964, 104 genes, copy number 6–14 (within-gene range 3–14) (broad region; genes not listed).
- chr2:44,996,413–61,051,990, 214 genes, copy number 5–7 (broad region; genes not listed).
- chr2:84,423,528–85,354,531, 22 genes, copy number 8–13 (within-gene range 1–13): SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT.
- chr2:90,100,236–90,235,370, 11 genes, copy number 7: IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr2:185,547,135–205,798,133, 310 genes, copy number 5–6 (broad region; genes not listed).
- chr3:85,992,183–86,362,474, 6 genes, copy number 7 (within-gene range 3–7): CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284.
- chr3:163,026,396–198,123,232, 629 genes, copy number 5–10 (broad region; genes not listed).
- chr7:63,768,257–67,239,519, 146 genes, copy number 5–14 (broad region; genes not listed).
- chr8:38,176,533–38,601,200, 17 genes, copy number 18 (within-gene range 1–18): BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr9:31,505,280–31,645,160, 3 genes, copy number 5: MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:136,546,173–136,617,181, 3 genes, copy number 5: MIR4674, NALT1, LINC01451.
- chr9:136,844,415–136,848,801, 1 gene, copy number 5 (within-gene range 3–5): AJM1.
- chr10:52,230,398–53,766,614, 12 genes, copy number 5 (within-gene range 3–5): PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:59,551,404–61,001,440, 15 genes, copy number 5: MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P.
- chr10:120,851,305–122,846,175, 32 genes, copy number 5–7 (within-gene range 2–7): WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, C10orf120, DMBT1L1, CUZD1.
- chr11:120,111,286–120,988,906, 12 genes, copy number 8: TRIM29, AP000679.1, OAF, POU2F3, AP001150.1, TLCD5, ARHGEF12, 7SK, GRIK4, ELOCP22, AP004147.1, HMGB1P42.
- chr12:66,767–37,576,384, 832 genes, copy number 6–7 (broad region; genes not listed).
- chr12:60,341,824–60,419,293, 3 genes, copy number 7: Y_RNA, AC090022.1, AC090022.2.
- chr12:63,558,913–68,671,901, 120 genes, copy number 5–15 (broad region; genes not listed).
- chr13:27,343,687–35,673,022, 131 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr14:104,857,792–104,896,770, 2 genes, copy number 5: AL583810.1, CEP170B.
- chr14:105,620,506–105,626,066, 1 gene, copy number 5 (within-gene range 4–5): IGHG4.
- chr14:105,664,633–105,669,843, 1 gene, copy number 6 (within-gene range 2–6): IGHGP.
- chr19:917,287–921,005, 1 gene, copy number 7: KISS1R.
- chr19:27,638,483–32,587,453, 84 genes, copy number 5–8 (broad region; genes not listed).
- chr21:7,744,962–8,680,934, 28 genes, copy number 6–12: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr21:10,640,028–13,980,437, 38 genes, copy number 6: AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P.

Autosomal genes at a single copy (total copy number 1): 4,599. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
